Surgical pathology report (de-identified scan), TCGA case TCGA-MB-A8JL, project TCGA-SARC (Sarcoma), tissue source site University of Minnesota, specimen TCGA-MB-A8JL-01A (Primary Tumor).

[page 1 of 4]
SPECIMEN(S):

A: Left axillary sentinel lymph node

B: Left breast

C: Right breast

FINAL DIAGNOSIS:

A. Lymph node, left axillary sentinel, biopsy

- No evidence of malignancy in one lymph node (0/1)

B. Breast, left, mastectomy:

- Leiomyosarcoma, intermediate grade
- Tumor measures 5.5 x 5.2 x 4.5 cm
- Biopsy site changes with hemorrhage.
- Margin widely negative (all greater than 1.8 cm)
- Fat necrosis
- Cysts with apocrine metaplasia
- See microscopic for discussion and tumor synoptic

C. Breast, right, mastectomy

- Simple ductal hyperplasia without atypia
- Cysts with apocrine metaplasia
- Duct ectasia
- Skin, nipple, and resection margins unremarkable
- No evidence of atypical hyperplasia, in situ carcinoma, or invasive carcinoma

CLINICAL HISTORY:

The patient is a year-old woman with a left breast leiomyosarcoma.

Operative Procedure: Left simple mastectomy, left sentinel node biopsy, and right simple mastectomy.

GROSS:

A. The first container is labeled "A - left axillary sentinel lymph node." The specimen consists of a 2.5 x 2.4 x 1.5 cm fragment of yellow-tan fibrofatty tissue. The specimen is serially sectioned and entirely submitted as A1 to A3.

B. The specimen consists of a 1535 gm, 25 cm medial to lateral by 22 cm superior to inferior by 5.0 cm anterior to posterior left mastectomy specimen. Representative tissue was procured for potential future studies from specimen B. The posterior deep margin is inked black, the anterior superior margin is inked blue, and the anterior inferior margin is inked green. The skin ellipse measures 9.4 x 7.9 cm. The nipple is everted and measures 4.2 x 2.8 x 0.6 cm. The mass is

ICD-O-3
Leiomyosarcoma NOS 8890/3
Site ^{CLF} Chest NOS C49.3
^{path} Breast NOS C50.9
JW 1/27/14

[page 2 of 4]
11.9 cm from the medial margin and 7.4 cm from the lateral margin. In the upper half of the breast near the midline there is a 1.5 x 1.4 x 0.6 cm firm, tan-white nodule. This nodule is 5.5 cm superior to the main mass and is 1.8 cm to the anterior superior margin and 4.5 cm to the posterior deep margin. The mass is greater than 2 cm from all other margins. There are no other masses or lesions identified. The breast is composed of approximately 25% fibrous tissue and 75% fatty tissue. The specimen is serially sectioned to reveal a solid tan and hemorrhagic mass that measures 5.5 x 5.2 x 4.5 cm. The mass is 1.3 cm to the nearest (deep) margin. It is 2.8 cm from the anterior inferior margin.

Specimen B was collected from the OR at _____ specimen was received in the lab at _____ and the specimen was placed in formalin at _____ on _____

Summary of sections:

- B1 - mass to deep (posterior) margin.
- B2-B5 - representative sections of tumor.
- B6 - additional pale tan nodule to interior blue margin.
- B7 - remainder of additional nodule.
- B8 - upper medial quadrant.
- B9 - lower medial quadrant.
- B10 - upper lateral quadrant.
- B11 - lower lateral quadrant.
- B12 - nipple.

C. The next container is labeled "C - right breast." The specimen consists of a 1735 gm, 3 x 23.5 x 5.5 cm right mastectomy specimen. The skin ellipse measures 9.3 x 5.5 cm. The nipple measures 1.3 x 1.3 x 1.0 cm. The anterior superior margin is inked blue, the anterior inferior margin is inked green, and the posterior deep margin is inked black. The specimen is serially sectioned to reveal an area of potential hemorrhagic fat necrosis that measures 3.5 x 2.5 x 2.9 cm. Representative sections of this area are submitted. All of the area of potential fat necrosis is submitted. There are no other masses or lesions identified. The area of fat necrosis is in the lower medial quadrant. The area of potential fat necrosis is 1.6 cm from the posterior margin and is 1.4 cm from the anterior inferior margin.

Specimen C was collected in the OR at _____ and the specimen was placed in formalin at _____ on _____

Summary of sections:

- C1-C9 - area of fat necrosis.
- C10-C11 - the upper medial quadrant.

[page 3 of 4]
C12-C13 - the lower medial quadrant.
C14-C15 - the upper lateral quadrant.
C16-C17 - the lower lateral quadrant.
C18 - nipple. MICROSCOPIC:

Microscopic examination is performed.

The left breast shows a tumor with features similar to a prior consult immunostains on that case were consistent with a leiomyosarcoma. Sarcomas in the breast always raise concern for a sarcomatoid carcinoma. The histologic sections of this current case again show no evidence of ductal carcinoma in situ or a more typical invasive ductal carcinoma, such that we not believe that there is evidence that this is a sarcomatoid carcinoma. Likewise, there is no evidence in the sections of a pre-existing phyllodes tumor. Thus, the best evidence is that this should be considered as a primary breast sarcoma. For additional details, see below.

SOFT TISSUE: Resection

Procedure: Mastectomy

Tumor Site: Left breast

Tumor Size: Greatest dimension: 5.5 cm

Macroscopic Extent of Tumor Subcutaneous/suprafascial
Histologic Type (World Health Organization [WHO] classification of soft tissue tumors) Leiomyosarcoma

Mitotic Rate: 21/10 high-power fields (HPF)

Necrosis (macroscopic or microscopic): Not identified

Histologic Grade (French Federation of Cancer Centers Sarcoma Group [FNCLCC]): Grade 2/3

Margins

Margins negative for sarcoma

Distance of sarcoma from closest margin: 1.8 cm to anterior/superior margin, others more widely negative

Lymph-Vascular Invasion: Not identified

Perineural Invasion: Not identified

[page 4 of 4]
Pathologic Staging (pTNM)

Primary Tumor (pT)

pT2a: Tumor more than 5 cm in greatest dimension, superficial tumor

Regional Lymph Nodes (pN)

pN0: No regional lymph node metastasis

Number of Lymph Nodes Examined: 1

Number of Lymph Nodes Involved: 0

Distant Metastasis (M)

M0: Distant metastasis clinically absent

Source: NCI Genomic Data Commons file d7e927d2-00ea-4765-9254-2baad10050ed (TCGA-MB-A8JL.6D0F6576-90C5-40AC-A3F8-42EE94C1A7D3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).